Gene-level copy-number profile of tumor specimen TCGA-DD-AAEG-01A from TCGA case TCGA-DD-AAEG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.8 years (21,853 days).
Specimen TCGA-DD-AAEG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.3c5d098e-cfe7-44dc-888b-cb538061e707.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAEG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3c38d37f-4c1d-4157-a1c1-c0fd7a379df2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,022; copy number 2: 43,231; copy number 3: 4,599; copy number 4: 17; copy number 6: 3,881; copy number 7: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAEG-01A-11D-A38W-01): tumor purity 0.83, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,951 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 6 (broad region; genes not listed).
- chr6:57,314,805–68,093,001, 70 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr8:29,527,312–31,598,204, 53 genes, copy number 6: AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3, AC068672.1, AC090816.1, RNA5SP261.
- chr8:31,827,238–32,139,495, 2 genes, copy number 6: AC068931.1, NRG1-IT1.
- chr8:66,870,749–145,066,685, 1,222 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,022. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
